Surgical pathology report (de-identified scan), TCGA case TCGA-14-0867, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Emory University, specimen TCGA-14-0867-01A (Primary Tumor).

[page 1 of 2]
AP Report

* Final Report *

Document Type: AP Report
Document Date: [REDACTED]
Document Status: Auth (Verified)
Document Title: Anatomic Pathology Report
Encounter info: [REDACTED]

14-0867

* Final Report *

Anatomic Pathology Report

Patient: [REDACTED] . Accession Number: [REDACTED]
Patient Number: [REDACTED] Date Collected: [REDACTED]
Financial Number: [REDACTED] Date Received: [REDACTED]
Room/Bed: [REDACTED] PT: [REDACTED]
Admitting Physician: [REDACTED]
Ordering Physician: [REDACTED]

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

1. BRAIN, CRANIOTOMY, BIOPSY, FS1A:
- GLIOBLASTOMA MULTIFORME (WHO GRADE IV).
2. BRAIN, CRANIOTOMY, BIOPSY:
- GLIOBLASTOMA MULTIFORME (WHO GRADE IV).

SPECIMEN:

1. Right temporal brain lesion, [REDACTED]
2. Right temporal brain lesion.

CLINICAL HISTORY/OPERATIVE FINDINGS:

NAME OF OPERATION: Craniotomy tumor resection.

PREOPERATIVE DIAGNOSIS: Brain tumor.

GROSS DESCRIPTION:

Printed by: [REDACTED]
Printed on: [REDACTED]

Page 1 of 2
(Continued)

[page 2 of 2]
[REDACTED]

AP Report

[REDACTED], [REDACTED] - [REDACTED]

* Final Report *

[REDACTED]

The specimen is received in two parts, each labeled with the patient's name and hospital number.

Specimen #1 is received fresh for intraoperative consultation, labeled "right temporal brain lesion." The specimen consists of a portion of tan-brown, soft tissue measuring in aggregate, 1.3 x 1.0 x 0.6 cm. A frozen section is performed on a portion of the specimen. The remainder of the cryoblock is submitted in lens paper in cassette "FS1A." The entire remainder of the specimen is submitted in lens paper in cassette "1B."

Specimen #2 is received in formalin, labeled "right temporal brain lesion." The specimen consists of multiple portions of red-tan, soft tissue, measuring 3.0 x 3.0 x 0.6 cm. The entire specimen is submitted in lens paper in cassette "2A."

[REDACTED]

INTRAOPERATIVE CONSULTATION:

FS1A: RIGHT TEMPORAL BRAIN LESION (FROZEN SECTION): GLIOBLASTOMA MULTIFORME.

[REDACTED]

TISSUE COMMITTEE CODE:

1

Fellow: [REDACTED]

The pathologist has reviewed and interpreted the case with the resident/fellow.

ICD-9 CODES:

191.2

Source: NCI Genomic Data Commons file 2aaa2ed0-83b4-415e-88db-bb9da7a80972 (TCGA-14-0867.6281ED47-96E8-4226-BEDD-EDB6318C3A57.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).